Somatic mutation profile of tumor specimen TCGA-AO-A12H-01A (aliquot TCGA-AO-A12H-01A-11D-A10Y-09) from TCGA case TCGA-AO-A12H, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.9 years (25,515 days).
Specimen TCGA-AO-A12H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2974528a-0903-47d6-b52e-7ac465878a67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A12H-10A (Blood Derived Normal), aliquot TCGA-AO-A12H-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c95dadc-a614-459e-9bf0-eb5dc34179d5

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Ins 2, Nonsense Mutation 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 31/66 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CAPRIN1 | c.1624C>G p.Q542E | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.814); catalogued as rs772325651, COSV58220729; called by muse, mutect2, varscan2
- CHD3 | c.3409C>T p.R1137* | Nonsense Mutation (SNP) | VAF 16/331 reads (5%) | catalogued as rs774094485; called by muse, mutect2
- DIP2B | c.4214A>C p.Y1405S | Missense Mutation (SNP) | VAF 81/169 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV56586809; called by muse, mutect2, varscan2
- DPPA3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV100559921, COSV61503207; called by muse, mutect2, varscan2
- ERC1 | c.1783A>T p.S595C (on ENST00000360905 / NM_178040.4; = p.S567C on NM_178039.4) | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as COSV61696770; called by muse, mutect2, varscan2
- KDM4D | c.370A>T p.K124* | Nonsense Mutation (SNP) | VAF 37/102 reads (36%) | catalogued as COSV58635198; called by muse, mutect2, varscan2
- MINK1 | c.566T>A p.I189N | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61791037; called by muse, mutect2, varscan2
- NF1 | c.3748C>T p.R1250W | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1452005208, CS1512932, COSV62203418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRK | c.3437A>G p.N1146S | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99686317; called by muse, mutect2
- PHLPP2 | c.1648C>T p.L550F | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62425289; called by muse, mutect2, varscan2
- PRPF19 | c.859A>C p.T287P | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs201780573; called by muse, mutect2
- RYR3 | c.9406A>G p.M3136V (on ENST00000389232; = p.M3137V on NM_001036.6) | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV66797717; called by muse, mutect2, varscan2
- SRRD | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 87/213 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV53226741; called by muse, mutect2, varscan2
- SWT1 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778215456, COSV62256656; called by muse, mutect2, varscan2
- WDR26 | c.1150G>T p.D384Y (on ENST00000414423 / NM_001379403.1; = p.D284Y on NM_025160.7) | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54357117; called by muse, mutect2, varscan2
- KMT2C | c.2409dup p.L804Sfs*2 | Frame Shift Ins (INS) | VAF 48/530 reads (9%) | called by pindel, varscan2
- RBM12 | c.2428_2448del p.P810_P816del | In Frame Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, varscan2
- USP9X | c.6955dup p.S2319Kfs*2 | Frame Shift Ins (INS) | VAF 125/361 reads (35%) | called by mutect2, pindel, varscan2
- DCAF12L2 | c.498C>T p.T166= | Silent (SNP) | VAF 51/138 reads (37%) | catalogued as COSV63581191; called by muse, mutect2, varscan2
- DNAH11 | c.2775C>T p.H925= | Silent (SNP) | VAF 88/245 reads (36%) | catalogued as rs1173313331, COSV60939732; called by muse, mutect2, varscan2
- SALL1 | c.957C>T p.I319= | Silent (SNP) | VAF 48/156 reads (31%) | catalogued as COSV51760196; called by muse, mutect2, varscan2
- SLFN5 | c.2598G>A p.P866= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs199777740, COSV55481992; called by muse, mutect2, varscan2
- MIR410 | n.33C>T | RNA (SNP) | VAF 12/164 reads (7%) | catalogued as rs369101854; called by muse, mutect2
